Somatic mutation profile of tumor specimen TARGET-10-PARCTN-09A (aliquot TARGET-10-PARCTN-09A-01D) from TARGET case TARGET-10-PARCTN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.7 years (3,908 days).
Specimen TARGET-10-PARCTN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bca90bb8-c79d-46a1-a517-1f4757a685f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARCTN-10A (Blood Derived Normal), aliquot TARGET-10-PARCTN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2809bd0b-90ed-42da-bbc9-30b318caefd0

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 5'Flank 1, Intron 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS3 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377163219; called by muse, mutect2, varscan2
- FSTL4 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs371473849; called by muse, mutect2, varscan2
- ANGEL1 | c.919C>A p.Q307K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- CENATAC | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FPR1 | c.695G>A p.G232D | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- NKX2-1 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2
- PHIP | c.1352G>A p.W451* | Nonsense Mutation (SNP) | VAF 2/11 reads (18%) | called by muse, mutect2
- PPP1R1C | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- SDK1 | c.2055C>T p.A685= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs151044664; called by muse, mutect2, varscan2
- DST | c.21999+505G>A | Intron (SNP) | VAF 24/49 reads (49%) | catalogued as rs774799170; called by muse, mutect2, varscan2
- TIGIT | chr3:114293994 C>T | 5'Flank (SNP) | VAF 41/77 reads (53%) | called by muse, mutect2, varscan2
